Somatic mutation profile of tumor specimen TCGA-2A-A8VT-01A (aliquot TCGA-2A-A8VT-01A-11D-A377-08) from TCGA case TCGA-2A-A8VT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.5 years (17,365 days).
Specimen TCGA-2A-A8VT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 639a0b68-a791-4498-a8de-7a2bdfb12cb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8VT-10A (Blood Derived Normal), aliquot TCGA-2A-A8VT-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d1cb21b-de1f-403c-a31a-d228b5fd70bb

The open-access MAF lists 42 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 4, Splice Region 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAX6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as rs1057517785, CM930573, COSV99570800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-2A>G p.X33_splice | Splice Site (SNP) | VAF 43/85 reads (51%) | hotspot (GDC flag); catalogued as rs879254212, COSV52678373, COSV52848662, COSV53375861, COSV53887648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALPP | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204596703, COSV101235191; called by muse, mutect2, varscan2
- ANXA2 | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100222146; called by muse, mutect2
- ARHGAP12 | c.1842A>T p.K614N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1286692379, COSV100260910; called by muse, mutect2, varscan2
- C10orf71 | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60505226, COSV60507803; called by muse, mutect2, varscan2
- C9 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99662560; called by muse, mutect2, varscan2
- CD40 | c.674A>T p.K225M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100953872; called by muse, mutect2, varscan2
- CLEC4F | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99714013; called by muse, mutect2
- COQ3 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV99633035; called by muse, mutect2
- E2F8 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1283331179, COSV100001771; called by muse, mutect2, varscan2
- GALT | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs773766027, COSV101122805; called by muse, mutect2, varscan2
- GOLGA3 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs1025627053, COSV52639232; called by muse, mutect2, varscan2
- GOLM1 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99974507; called by muse, mutect2, varscan2
- GPKOW | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV50246512; called by muse, mutect2, varscan2
- HLTF | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100027137; called by muse, mutect2, varscan2
- HNRNPA1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV99267881; called by muse, mutect2, varscan2
- HS6ST2 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100897465; called by muse, mutect2, varscan2
- IZUMO1 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99711113; called by muse, mutect2
- LRP1B | c.5018C>T p.T1673M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs199519370, COSV67279819; called by muse, mutect2, varscan2
- LRRTM1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54447863; called by muse, mutect2, varscan2
- LY9 | c.1594A>T p.T532S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV99627466; called by muse, mutect2
- MACC1 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100256294; called by muse, mutect2, varscan2
- MYH11 | c.2924C>T p.T975M | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs763795192, COSV55563181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10H2 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100008888; called by muse, mutect2
- RAD54B | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100280216; called by mutect2, varscan2
- RYR1 | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100614899, COSV100617025; called by muse, mutect2, varscan2
- SLC1A5 | c.1412A>T p.N471I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314824; called by muse, varscan2
- STMN2 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99626879; called by muse, mutect2, varscan2
- TAB2 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV99645117; called by muse, mutect2, varscan2
- TKFC | c.777C>A p.G259= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as COSV101204227; called by muse, mutect2, varscan2
- TYRP1 | c.636T>G p.D212E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101141466; called by muse, mutect2, varscan2
- USH2A | c.10082C>A p.T3361N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100242725; called by muse, mutect2
- PRAMEF19 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHNAK | c.17559G>T p.V5853= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV99949628; called by muse, mutect2, varscan2
- CHD9 | c.609T>A p.S203= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV101272181; called by muse, mutect2, varscan2
- DSTN | c.15G>T p.V5= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99855280; called by muse, mutect2
- FAT4 | c.10386A>G p.G3462= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs1353675162, COSV100630214; called by muse, mutect2, varscan2
- GALNT12 | c.1464C>T p.F488= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs772731021, COSV100899203; called by muse, mutect2, varscan2
- OR4C13 | c.336A>C p.L112= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV101634243; called by muse, mutect2
- PIK3AP1 | c.1617C>T p.T539= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100226222; called by muse, mutect2
- MYH7 | c.4169+214C>T | Intron (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100806659; called by muse, mutect2, varscan2
